Somatic mutation profile of tumor specimen 0DVDU8 from CCDI case PBCKXG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.0 years (2,540 days).
Specimen 0DVDU8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a6c268b-86b2-4c76-9862-5552704c8f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVDUW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bede4070-e418-45af-98e1-877481162445

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, 3'UTR 1, Splice Site 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 110/199 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as CM092616, HD971482, COSV56544941, COSV56556284, COSV56567454; called by muse, mutect2, varscan2
- BOD1L1 | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 268/629 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- EPB41L4A | c.1224C>A p.S408R | Missense Mutation (SNP) | VAF 60/841 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2
- GLI4 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2
- SLC12A7 | c.2848-1G>A p.X950_splice | Splice Site (SNP) | VAF 38/449 reads (8%) | called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 33/649 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZNF519 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 12/379 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SLC9A3R2 | c.690C>T p.P230= | Silent (SNP) | VAF 48/373 reads (13%) | catalogued as rs760607408; called by muse, mutect2, varscan2
- CTBS | c.*2059T>A | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- DNAJC2 | c.573-66A>G | Intron (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- MTMR8 | c.-66C>A | 5'UTR (SNP) | VAF 50/74 reads (68%) | catalogued as rs905598160; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 18/106 reads (17%) | called by muse, varscan2
